Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A6TZ, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A6TZ-01A (Primary Tumor).

Morphology shows astrocytic differentiation. Mitotic activity not detectable. Proliferation 2%.

Diagnosis

Astrocytoma WHO grade II

CBCE ICD-8-3
Astrocytoma, grade II
path 940043
Astrocytoma, diffuse 940043
Site Brain, supratentorial
C71.0
JW 7/25/13

untranslated original report
is housed at the BCR

Source: NCI Genomic Data Commons file baa62728-14de-4435-9f0d-b070276d40ea (TCGA-S9-A6TZ.45EFB1C3-792D-4A76-B8D9-2AE35F151F03.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).